Somatic mutation profile of tumor specimen HCM-CSHL-0247-C18-06A (aliquot HCM-CSHL-0247-C18-06A-11D-A78T-36) from HCMI case HCM-CSHL-0247-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.5 years (27,936 days).
Specimen HCM-CSHL-0247-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a472532-16bf-46b8-99ac-8046be343164.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0247-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0247-C18-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5664258b-6a58-4ab3-9cce-89473a2ef3b1

The open-access MAF lists 167 somatic variants for this specimen: 107 protein-altering or splice-affecting, 43 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 43, Nonsense Mutation 6, Intron 5, RNA 5, 5'UTR 4, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, In Frame Del 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 96/151 reads (64%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 48/163 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 820/1033 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs763583101; called by muse, mutect2, varscan2
- AL358113.1 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 351/859 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs1037430967, COSV61957022; called by muse, mutect2, varscan2
- ALPK3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 243/367 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV51940688; called by muse, mutect2, varscan2
- AP1M2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs761767257; called by muse, mutect2, varscan2
- ASAP1 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 102/463 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1365555616; called by muse, mutect2, varscan2
- ATP9B | c.1481C>T p.T494M | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs775046912; called by muse, mutect2
- C14orf93 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs759429838, COSV52986387; called by muse, mutect2
- CACNA1A | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs756562814, COSV64200832, COSV64211473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAP2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs200521747, COSV57731947; called by muse, mutect2, varscan2
- CDH23 | c.4519C>T p.R1507W | Missense Mutation (SNP) | VAF 187/476 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs760927863, COSV56477037; called by muse, mutect2, varscan2
- CDH7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- CNTN5 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 133/626 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs1398463099, COSV54329471; called by muse, mutect2, varscan2
- COL4A2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 115/719 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773576081; called by muse, mutect2, varscan2
- CPB1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs150860615, COSV99294138; called by muse, mutect2, varscan2
- CRNKL1 | c.2480A>C p.K827T | Missense Mutation (SNP) | VAF 56/1054 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV58548445; called by muse, mutect2
- CSMD3 | c.5836C>A p.R1946S (on ENST00000297405 / NM_001363185.1; = p.R1842S on NM_052900.3) | Missense Mutation (SNP) | VAF 268/552 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as rs377290204; called by muse, mutect2, varscan2
- CTRB1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs749947761; called by mutect2, varscan2
- DIPK1B | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 221/670 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770330516, COSV63038081; called by muse, mutect2, varscan2
- DLG2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 64/502 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV65832294, COSV65853967; called by muse, mutect2, varscan2
- EIF2B5 | c.1630G>A p.E544K (on ENST00000647909; = p.E536K on NM_003907.3) | Missense Mutation (SNP) | VAF 174/608 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV56605595; called by muse, mutect2, varscan2
- GLI3 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 398/1354 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as rs1296035859, COSV67890481; called by muse, varscan2
- GLI3 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 820/1452 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs755227076, COSV67887250; ClinVar: uncertain significance; called by muse, varscan2
- GRM3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 205/601 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs112122758, COSV100862026, COSV64478495; called by muse, mutect2, varscan2
- HLA-DOA | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as rs200140467; called by muse, mutect2
- HPCAL1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV57145974; called by muse, mutect2, varscan2
- HTR7 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 198/500 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV53286886; called by muse, mutect2, varscan2
- KLHL24 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs1394330213; called by muse, mutect2, varscan2
- LDAH | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 89/383 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV52971512; called by muse, mutect2, varscan2
- LRRC37A3 | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 87/583 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.305); catalogued as rs527816573; called by muse, mutect2, varscan2
- MNDA | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1329858284; called by muse, mutect2, varscan2
- MSLNL | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 156/411 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765899968, COSV53498896; called by muse, mutect2, varscan2
- NEB | c.18493G>A p.G6165R | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.44); PolyPhen probably damaging (1); catalogued as rs1480807112, COSV99419848; ClinVar: uncertain significance; called by muse, mutect2
- NLRC5 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs866090118, COSV52660803; called by muse, mutect2, varscan2
- NOL6 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 184/533 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs756516749; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 133/725 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.803G>A p.R268H (on ENST00000259318 / NM_001136562.3; = p.R499H on NM_007203.5) | Missense Mutation (SNP) | VAF 166/411 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs368590919; called by muse, varscan2
- PCDHA12 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 422/1024 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs781787046, COSV56485542; called by muse, mutect2, varscan2
- PCDHGA6 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 416/981 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.052); catalogued as rs919176873, COSV53913907; called by muse, mutect2, varscan2
- PKD1L2 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.401); catalogued as rs779408230; called by muse, mutect2, varscan2
- RIMBP2 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs763832408; called by muse, mutect2, varscan2
- RNF2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs1335456103, COSV62279097; called by muse, mutect2, varscan2
- SCG2 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59538910, COSV59540439; called by muse, mutect2, varscan2
- SERPINB2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs922692149, COSV55091465; called by muse, mutect2, varscan2
- SIN3A | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 89/141 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845221; called by muse, mutect2, varscan2
- SLC6A2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 251/729 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776659407, COSV54923884; called by muse, mutect2, varscan2
- SOX9 | c.1261_1267dup p.F423* | Frame Shift Ins (INS) | VAF 157/228 reads (69%) | catalogued as COSV55427921; called by mutect2, varscan2
- SPDEF | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 60/414 reads (14%) | catalogued as rs770126986, COSV100927845; called by muse, mutect2, varscan2
- TENM2 | c.2416G>A p.E806K (on ENST00000518659 / NM_001122679.2; = p.E574K on NM_001080428.3) | Missense Mutation (SNP) | VAF 162/343 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs376627738; called by muse, mutect2, varscan2
- TNXB | c.5065G>A p.G1689S (on ENST00000647633; = p.G1442S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 212/558 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762480960; called by muse, mutect2, varscan2
- UBAP1L | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 142/216 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs933188149; called by muse, mutect2, varscan2
- USP13 | c.1966T>G p.S656A | Missense Mutation (SNP) | VAF 66/491 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as rs750485320; called by muse, mutect2, varscan2
- WDR7 | c.4364C>T p.A1455V | Missense Mutation (SNP) | VAF 250/353 reads (71%) | SIFT tolerated (0.64); PolyPhen benign (0.181); catalogued as rs750926404; called by muse, mutect2, varscan2
- ZNF251 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 222/400 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs200114017; called by muse, mutect2, varscan2
- ZNF747 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 344/1003 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs890550251, COSV53224406; called by muse, mutect2, varscan2
- APC | c.3209del p.N1070Ifs*56 | Frame Shift Del (DEL) | VAF 157/295 reads (53%) | called by mutect2, pindel, varscan2
- APOB | c.10788G>T p.M3596I | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BNC1 | c.1655A>G p.E552G | Missense Mutation (SNP) | VAF 182/459 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6orf89 | c.933A>G p.I311M (on ENST00000373685; = p.I318M on NM_152734.4) | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CAAP1 | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- CDH6 | c.1301A>T p.D434V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CLASP2 | c.4067C>G p.A1356G (on ENST00000359576; = p.A1355G on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- COL6A5 | c.2828A>G p.N943S | Missense Mutation (SNP) | VAF 444/757 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CTNNA3 | c.1652T>A p.V551D | Missense Mutation (SNP) | VAF 278/715 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DACT2 | c.2024dup p.S676Vfs*13 | Frame Shift Ins (INS) | VAF 73/247 reads (30%) | called by mutect2, pindel, varscan2
- DOC2A | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 97/565 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- DOCK2 | c.159A>T p.K53N | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EPHA5 | c.2107C>G p.P703A | Missense Mutation (SNP) | VAF 105/146 reads (72%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM217B | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 380/740 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- FAM72B | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 157/439 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNG11 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- GRM1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ | c.2752T>A p.F918I | Missense Mutation (SNP) | VAF 182/212 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HTR3A | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 226/596 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); called by muse, varscan2
- INHBA | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 390/747 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITGA9 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 209/316 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ITGB3 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 330/950 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- L3MBTL4 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRRC24 | c.426_428del p.F142del | In Frame Del (DEL) | VAF 222/823 reads (27%) | called by pindel, varscan2
- MAP1A | c.6785A>G p.E2262G | Missense Mutation (SNP) | VAF 353/519 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MMP27 | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- NAP1L3 | c.1132A>T p.I378L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.643); called by muse, mutect2
- NKTR | c.3205A>G p.K1069E | Missense Mutation (SNP) | VAF 77/114 reads (68%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTM | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 182/503 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PC | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 149/614 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHLDB2 | c.2801G>T p.S934I (on ENST00000393925 / NM_001134439.2; = p.S891I on NM_145753.2) | Missense Mutation (SNP) | VAF 30/525 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PHRF1 | c.2165A>T p.Q722L (on ENST00000264555 / NM_001286581.2; = p.Q721L on NM_020901.4) | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PPP1CB | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 161/249 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTPRZ1 | c.2736C>A p.S912R | Missense Mutation (SNP) | VAF 66/393 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAPGEF6 | c.4715G>C p.R1572T | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- RSU1 | c.831_*6del | Nonstop Mutation (DEL) | VAF 82/407 reads (20%) | called by mutect2, pindel, varscan2
- SALL3 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 236/328 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SI | c.1088A>T p.K363M | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2
- SLC22A4 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 310/456 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLIT1 | c.2627G>A p.W876* | Nonsense Mutation (SNP) | VAF 165/389 reads (42%) | called by muse, mutect2, varscan2
- SMG1 | c.9077T>A p.L3026Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMPDL3A | c.479T>A p.L160Q | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SSBP4 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SSC5D | c.2251T>C p.S751P | Missense Mutation (SNP) | VAF 78/111 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TBC1D32 | c.2669del p.L890Yfs*33 | Frame Shift Del (DEL) | VAF 93/441 reads (21%) | called by mutect2, pindel, varscan2
- TEX51 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TNXB | c.7766G>T p.G2589V (on ENST00000647633; = p.G2342V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/1016 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP48 | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 140/202 reads (69%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UST | c.777C>A p.C259* | Nonsense Mutation (SNP) | VAF 164/332 reads (49%) | called by muse, mutect2
- A4GNT | c.513C>T p.I171= | Silent (SNP) | VAF 255/920 reads (28%) | called by muse, mutect2, varscan2
- ABCG4 | c.78C>T p.D26= | Silent (SNP) | VAF 208/552 reads (38%) | catalogued as rs373824430; called by muse, mutect2, varscan2
- ADAMTS20 | c.3663T>G p.A1221= | Silent (SNP) | VAF 47/180 reads (26%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.1791G>A p.G597= | Silent (SNP) | VAF 170/472 reads (36%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1071C>T p.N357= | Silent (SNP) | VAF 134/423 reads (32%) | catalogued as rs937679166; called by muse, mutect2, varscan2
- APOBEC3F | c.708C>T p.G236= | Silent (SNP) | VAF 96/236 reads (41%) | catalogued as COSV57910186; called by muse, mutect2
- CFAP61 | c.3576G>T p.P1192= | Silent (SNP) | VAF 61/680 reads (9%) | called by muse, mutect2
- CTNNA2 | c.351G>A p.S117= | Silent (SNP) | VAF 161/461 reads (35%) | catalogued as rs201020471, COSV63548922; called by muse, mutect2, varscan2
- CYP2D6 | c.264C>T p.R88= | Silent (SNP) | VAF 467/1940 reads (24%) | catalogued as rs1230147351; called by muse, mutect2, varscan2
- DAB2 | c.1386C>T p.P462= | Silent (SNP) | VAF 184/403 reads (46%) | catalogued as rs1232950773, COSV57917425; called by muse, mutect2, varscan2
- DPP10 | c.1321C>T p.L441= | Silent (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- EML3 | c.1587G>C p.L529= | Silent (SNP) | VAF 108/321 reads (34%) | called by muse, mutect2, varscan2
- FAM161A | c.90C>T p.Y30= | Silent (SNP) | VAF 311/795 reads (39%) | called by muse, mutect2, varscan2
- FAM227A | c.639G>A p.Q213= | Silent (SNP) | VAF 103/259 reads (40%) | called by muse, mutect2, varscan2
- FAT3 | c.11919G>A p.T3973= | Silent (SNP) | VAF 217/556 reads (39%) | catalogued as rs898299684, COSV53101021; called by muse, mutect2, varscan2
- FLCN | c.237G>A p.S79= | Silent (SNP) | VAF 63/568 reads (11%) | catalogued as rs771650940, COSV99550176; called by muse, mutect2, varscan2
- FOXO1 | c.1746C>T p.S582= | Silent (SNP) | VAF 208/256 reads (81%) | called by muse, mutect2, varscan2
- FRY | c.6315G>A p.L2105= | Silent (SNP) | VAF 131/726 reads (18%) | called by muse, mutect2, varscan2
- GAB4 | c.72G>A p.S24= | Silent (SNP) | VAF 132/401 reads (33%) | catalogued as rs1182743180; called by muse, mutect2, varscan2
- GALNT14 | c.1587C>T p.N529= | Silent (SNP) | VAF 141/457 reads (31%) | catalogued as rs145219116; called by muse, mutect2, varscan2
- GATA5 | c.675G>A p.P225= | Silent (SNP) | VAF 306/1049 reads (29%) | catalogued as rs144082730; called by muse, mutect2, varscan2
- GGT6 | c.780C>T p.S260= (on ENST00000574154 / NM_001122890.3; = p.S228= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 124/281 reads (44%) | catalogued as rs768266892, COSV99626686; called by muse, mutect2, varscan2
- HECW2 | c.1914G>A p.L638= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV53651191; called by muse, mutect2, varscan2
- HYDIN | c.14442C>T p.N4814= | Silent (SNP) | VAF 40/238 reads (17%) | catalogued as rs754046438, COSV101125029; called by muse, mutect2
- LMNB1 | c.1332C>T p.I444= | Silent (SNP) | VAF 180/488 reads (37%) | catalogued as rs779989576; called by muse, mutect2, varscan2
- MC2R | c.504C>T p.F168= | Silent (SNP) | VAF 186/265 reads (70%) | called by muse, mutect2, varscan2
- MESP1 | c.231C>T p.S77= | Silent (SNP) | VAF 87/133 reads (65%) | called by muse, mutect2, varscan2
- MUC12 | c.4041C>T p.D1347= (on ENST00000379442; = p.D1204= on NM_001164462.1) | Silent (SNP) | VAF 369/2062 reads (18%) | catalogued as rs1468499227; called by muse, varscan2
- MYO7A | c.6102G>A p.V2034= | Silent (SNP) | VAF 18/286 reads (6%) | catalogued as rs1265821797; called by muse, mutect2
- MYT1L | c.816C>T p.H272= | Silent (SNP) | VAF 136/327 reads (42%) | catalogued as rs751168400, COSV67728872; called by muse, mutect2, varscan2
- NBEA | c.6285G>C p.L2095= | Silent (SNP) | VAF 48/542 reads (9%) | called by muse, mutect2
- NPL | c.324C>T p.I108= | Silent (SNP) | VAF 196/524 reads (37%) | catalogued as rs369901524; called by muse, mutect2, varscan2
- OCM2 | c.15C>T p.D5= | Silent (SNP) | VAF 106/424 reads (25%) | catalogued as rs762988500, COSV57535963; called by muse, varscan2
- PIEZO2 | c.2976G>T p.V992= | Silent (SNP) | VAF 48/229 reads (21%) | called by muse, mutect2, varscan2
- PPT1 | c.363G>A p.R121= (on ENST00000433473; = p.R122= on NM_000310.4) | Silent (SNP) | VAF 221/339 reads (65%) | called by muse, mutect2, varscan2
- PRADC1 | c.237C>T p.N79= | Silent (SNP) | VAF 226/607 reads (37%) | catalogued as rs753244246; called by muse, mutect2, varscan2
- PROKR2 | c.420C>T p.Y140= | Silent (SNP) | VAF 139/483 reads (29%) | catalogued as rs199794008, CM085658; called by muse, mutect2, varscan2
- SCG2 | c.1107C>G p.L369= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV59541239; called by muse, mutect2
- SOX8 | c.915C>T p.G305= | Silent (SNP) | VAF 130/376 reads (35%) | catalogued as rs372544446, COSV53509080, COSV53510314; called by muse, mutect2
- TRPM2 | c.2292G>A p.P764= | Silent (SNP) | VAF 146/359 reads (41%) | catalogued as rs148173972; called by muse, mutect2, varscan2
- USP2 | c.705G>A p.T235= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs752095300, COSV52730776; called by muse, mutect2, varscan2
- WDR13 | c.456G>A p.T152= | Silent (SNP) | VAF 243/363 reads (67%) | catalogued as rs1556993839; called by muse, mutect2, varscan2
- ZNF775 | c.1203C>A p.G401= | Silent (SNP) | VAF 88/321 reads (27%) | called by muse, mutect2, varscan2
- AC011525.1 | n.801G>C | RNA (SNP) | VAF 32/470 reads (7%) | called by muse, mutect2
- C9orf62 | n.511G>T | RNA (SNP) | VAF 118/306 reads (39%) | catalogued as rs1011518817; called by muse, mutect2, varscan2
- CCDC169 | chr13:36227319 C>G | 3'Flank (SNP) | VAF 77/462 reads (17%) | called by muse, mutect2, varscan2
- CGB8 | c.-12G>T | 5'UTR (SNP) | VAF 152/254 reads (60%) | catalogued as rs200172544; called by muse, varscan2
- CINP | c.-11C>T | 5'UTR (SNP) | VAF 109/164 reads (66%) | catalogued as rs781568572; called by muse, mutect2, varscan2
- CPNE2 | c.928-520C>T | Intron (SNP) | VAF 127/361 reads (35%) | called by muse, mutect2, varscan2
- FAM74A3 | n.30G>A | RNA (SNP) | VAF 210/710 reads (30%) | catalogued as rs760580183; called by muse, mutect2, varscan2
- FSHB | c.-1G>A | 5'UTR (SNP) | VAF 157/401 reads (39%) | called by muse, mutect2, varscan2
- GYPB | c.37+2403G>T | Intron (SNP) | VAF 53/106 reads (50%) | called by muse, varscan2
- IKBKB | c.1516+42T>G | Intron (SNP) | VAF 316/585 reads (54%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.*186C>G | 3'UTR (SNP) | VAF 116/463 reads (25%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.746A>G | RNA (SNP) | VAF 34/390 reads (9%) | called by muse, mutect2
- PALM2AKAP2 | c.-23G>A | 5'UTR (SNP) | VAF 263/691 reads (38%) | called by muse, mutect2, varscan2
- PLCG2 | c.2307+89C>A | Intron (SNP) | VAF 188/496 reads (38%) | called by muse, mutect2, varscan2
- SFXN5 | c.945+4098C>T | Intron (SNP) | VAF 134/364 reads (37%) | catalogued as rs1037813559; called by muse, mutect2, varscan2
- SSPOP | n.12223A>T | RNA (SNP) | VAF 27/430 reads (6%) | called by muse, mutect2
- TMEM120A | c.*67C>T | 3'UTR (SNP) | VAF 159/269 reads (59%) | catalogued as rs782267943; called by muse, mutect2, varscan2
